CCDI case PBBVEW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/0ff56621-0848-4316-8cb8-aafd5ab04a57

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 9.2 years (3,354 days).

Biospecimens (3 samples)
- Sample 0DI1JU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI1V3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI201: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
